Somatic mutation profile of tumor specimen 0E1O0F from CCDI case PBCWBN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E1O0F: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4c9c613-911b-4f86-a18b-ff0993cbc106.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1NYK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e09a0758-a9e8-47af-952a-f8ac855ce416

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATG2B | c.3377T>G p.V1126G | Missense Mutation (SNP) | VAF 67/147 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs777659483; called by muse, mutect2, varscan2
- CIITA | c.3311C>T p.T1104M | Missense Mutation (SNP) | VAF 67/153 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs367805896; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TPPP | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 74/179 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs142128231; called by muse, mutect2, varscan2
- GDI2 | c.355G>A p.V119I | Missense Mutation (SNP) | VAF 9/251 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.419); called by muse, mutect2
- PAX9 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2
- CERCAM | c.180G>A p.R60= | Silent (SNP) | VAF 58/198 reads (29%) | called by muse, mutect2, varscan2
- TGFB1I1 | c.870C>T p.C290= (on ENST00000394863 / NM_001042454.3; = p.C273= on NM_015927.4) | Silent (SNP) | VAF 65/234 reads (28%) | called by muse, mutect2, varscan2
- MFGE8 | c.-14C>G | 5'UTR (SNP) | VAF 36/106 reads (34%) | called by muse, mutect2, varscan2
- RNF40 | c.1294-33G>A | Intron (SNP) | VAF 35/94 reads (37%) | catalogued as rs1016617749; called by muse, mutect2, varscan2
